CPTAC case SC-0171 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/19acf7d2-b099-4ce5-8d4e-b889dc2b4cb5

Demographics
Sex at birth: female; Vital status: Dead; Days to death: 1,552 days (4.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 64.0 years (23,376 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N1a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Last known disease status: With tumor; Days to last known disease status: 1,552 days (4.2 years); Progression or recurrence: yes; Days to recurrence: 30 days; Clark level: IV.
   Pathology details: Breslow thickness: 8.5.

Biospecimens (2 samples)
- Sample S-1701-012801: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 64 mg; Method of sample procurement: Tumor Resection.
- Sample S-1701-012802: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 112 mg; Method of sample procurement: Tumor Resection.
